Somatic mutation profile of tumor specimen 0DQ8XU from CCDI case PBCENI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,617 days).
Specimen 0DQ8XU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dcb269f-12ca-4bba-bf9c-f1508ad02631.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ8YE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/055ff345-8dcb-42e2-af26-dc3f288478c4

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Intron 2, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 2869/3223 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51784086; called by muse, mutect2, varscan2
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 41/842 reads (5%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 242/248 reads (98%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP002512.3 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 291/457 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs142752109; called by muse, mutect2, varscan2
- BMS1 | c.3280G>A p.D1094N | Missense Mutation (SNP) | VAF 322/675 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs1303300696, COSV65733868; called by muse, mutect2, varscan2
- EGFR | c.2170G>A p.G724S | Missense Mutation (SNP) | VAF 3583/3988 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1051753269, COSV51788393; ClinVar: not provided; called by muse, mutect2, varscan2
- FZD10 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 90/540 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs1392335994, COSV57473019; called by muse, mutect2, varscan2
- H4C3 | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 68/476 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.224); catalogued as rs775824271; called by muse, varscan2
- LVRN | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 226/494 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); catalogued as COSV100773351; called by muse, mutect2
- RNF39 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 74/554 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372233460; called by muse, mutect2, varscan2
- SZT2 | c.9637C>T p.R3213W (on ENST00000634258 / NM_001365999.1; = p.R3156W on NM_015284.4) | Missense Mutation (SNP) | VAF 67/482 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1483282139; called by muse, mutect2, varscan2
- XRN2 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 96/662 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs375973142; called by muse, mutect2, varscan2
- ANXA2 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 270/542 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 31/1091 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CNGA1 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 68/627 reads (11%) | called by muse, mutect2, varscan2
- MEGF11 | c.3000A>T p.E1000D | Missense Mutation (SNP) | VAF 290/687 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MLH1 | c.120A>C p.L40F | Missense Mutation (SNP) | VAF 110/683 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLE2 | c.1067A>G p.H356R | Missense Mutation (SNP) | VAF 55/437 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- SPATA31A1 | c.3121G>A p.V1041I | Missense Mutation (SNP) | VAF 33/374 reads (9%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 26/592 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- CHRNA6 | c.1278G>C p.S426= | Silent (SNP) | VAF 127/515 reads (25%) | catalogued as COSV99373082; called by muse, mutect2, varscan2
- MROH1 | c.2403C>T p.R801= | Silent (SNP) | VAF 161/352 reads (46%) | catalogued as rs1278933229; called by muse, mutect2, varscan2
- RGPD6 | c.18C>T p.A6= | Silent (SNP) | VAF 6/475 reads (1%) | catalogued as rs1466985607; called by muse, mutect2
- RIPOR1 | c.3291C>T p.D1097= (on ENST00000379312 / NM_001193522.2; = p.D1093= on NM_024519.4) | Silent (SNP) | VAF 212/456 reads (46%) | catalogued as rs1236158517, COSV50235100; called by muse, mutect2, varscan2
- SLC36A4 | c.951G>A p.L317= | Silent (SNP) | VAF 38/970 reads (4%) | called by muse, mutect2
- CSMD3 | c.9863-51C>G | Intron (SNP) | VAF 24/171 reads (14%) | called by muse, varscan2
- DDX17 | c.-36A>C | 5'UTR (SNP) | VAF 50/95 reads (53%) | called by muse, mutect2, varscan2
- MPZL1 | c.605+20dup | Intron (INS) | VAF 187/426 reads (44%) | catalogued as rs769778837; called by mutect2, varscan2
